Gene-level copy-number profile of tumor specimen TCGA-AF-4110-01A from TCGA case TCGA-AF-4110, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Age at diagnosis: 77.5 years (28,289 days).
Specimen TCGA-AF-4110-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.74a25ecb-fb62-474b-8816-d07ff9fe8011.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AF-4110-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/62d5ecb6-1acb-4042-a5a8-14702707cef9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 14; copy number 2: 9,440; copy number 3: 22,341; copy number 4: 18,872; copy number 5: 6,255; copy number 6: 584; copy number 8: 1,391; copy number 9: 909; copy number 15: 4; copy number 31: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AF-4110-01A-02D-1732-01): tumor purity 0.42, ploidy 3.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,573,767–6,748,969, 4 genes: AC007223.1, AC007012.2, AC007012.1, RNU7-99P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,310 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 8 (broad region; genes not listed).
- chr20:14,322,985–15,022,958, 10 genes, copy number 15–31: FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.
- chr20:16,272,104–16,573,448, 1 gene, copy number 9 (within-gene range 2–9): KIF16B.
- chr20:19,000,709–20,002,459, 9 genes, copy number 9 (within-gene range 2–9): AL135936.1, AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12.
- chr20:30,214,765–64,313,132, 899 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
